Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4H6, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4H6-01A (Primary Tumor).

Stomach, subtotal gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(+)/Muc6(+)/CD10(-), G type)

1. Location : lower third, Center at antrum, lesser curvature
2. Gross type : Borrmann type 2
3. Histologic type : Adenocarcinoma, tubular moderately differentiated (tub2)
4. Histologic type by Lauren : intestinal
5. Growth pattern: diffusely infiltrative growth pattern
6. Size : 4.8x4.3cm
7. Depth of invasion : invades subserosa (pT3)
8. Resection margin : free from carcinoma
safety margins: distal 3.4cm, proximal 6.0cm
9. Lymph node metastasis : metastasis to 3 out of 86 regional lymph nodes (pN2)
(lesser curvature 1/66, greater curvature 2/18, LN 0/2)
10. Lymphatic invasion : present, mild
11. Venous invasion : not identified
12. Perineural invasion : present, moderate
- Specimen labeled as "anvil ring", biopsy:
- No tumor.
- # Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

ICD-O-3

adenocarcinoma, tubular 8211/3

Site : stomach, antrum c 16.3

lw 9/27/12

Source: NCI Genomic Data Commons file fd3e3608-e60b-423a-99f5-1a3e33f65d7c (TCGA-HU-A4H6.D055A047-E2AA-4E73-A437-EB9B5E026ED0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).